Gene-level copy-number profile of tumor specimen TCGA-49-AARO-01A from TCGA case TCGA-49-AARO, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 39.8 years (14,527 days).
Specimen TCGA-49-AARO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e3f78a21-8869-44b9-9aaa-3558af812043.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-AARO-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3545c596-52a0-4021-90f9-32b46ddbd038

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,048; copy number 2: 19,201; copy number 3: 20,830; copy number 4: 13,653; copy number 5: 3,726; copy number 6: 1,054; copy number 7: 162; copy number 8: 40; copy number 9: 26; copy number 10: 7; copy number 11: 2; copy number 17: 32; copy number 21: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-AARO-01A-12D-A40Z-01): tumor purity 0.28, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 300 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,274,552–75,795,086, 44 genes, copy number 7–10: GDI2P2, AL513166.1, RPL31P12, AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360, LINC02238, RNA5SP50, AL591463.1, RNU4ATAC8P, LRRIQ3, FPGT, FPGT-TNNI3K, TNNI3K, AC093158.1, AC105271.1, LRRC53, ERICH3, ERICH3-AS1, AC135803.1, CRYZ, TYW3, AC133865.1, AC099786.3, AC099786.1, LHX8, AC099786.2, RNU6-622P, SLC44A5, AC093156.1, RNU6-503P, AL096829.1, AL137803.1, ACADM, DLSTP1, RABGGTB, SNORD45C, SNORD45A, SNORD45B.
- chr2:96,497,646–97,094,882, 28 genes, copy number 8 (within-gene range 4–8): NEURL3, AC013270.1, ARID5A, KANSL3, FER1L5, LMAN2L, CNNM4, MIR3127, CNNM3-DT, CNNM3, ANKRD23, ANKRD39, SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B.
- chr4:57,352,999–57,353,329, 1 gene, copy number 8: RPS26P24.
- chr6:65,836,930–66,728,904, 4 genes, copy number 8: ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P.
- chr7:54,330,670–55,433,742, 19 genes, copy number 7: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr12:31,959,370–34,249,958, 46 genes, copy number 7 (within-gene range 4–7): RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P, DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr12:55,820,960–58,813,060, 151 genes, copy number 7–21 (within-gene range 5–21) (broad region; genes not listed).
- chr12:59,450,673–60,096,071, 7 genes, copy number 8: RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1.

Autosomal genes at a single copy (total copy number 1): 1,048. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
